Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7474, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7474-01A (Primary Tumor).

ADDENDUM DISCUSSION:

The calculated MIB-1 labeling index is 2.3% consistent with a low grade glioma.

ADDENDUM DIAGNOSIS:

- 1, 2. BRAIN TUMOR, BIOPSY AND RESECTION:
OLIGOASTROCYTOMA (WHO GRADE II).
- MIB-1 LABELING INDEX = 2.3%

MICROSCOPIC DESCRIPTION:

1, 2. Microscopic examination reveals an infiltrative glioma. The tumor is composed of a predominant population of cells with oligodendroglial features, including mildly to moderately pleomorphic round nuclei with perinuclear halos. Scattered intermixed microgemistocytic forms are also identified. A second lesser population of cells, most prevalent on the frozen section material, shows astrocytic features. The astrocytic component consists of small cells with regular oval nuclei and prominent fibrillary processes, as observed on the smear material. Overall, the tumor appears moderately hypercellular and diffusely infiltrates the adjacent brain parenchyma. Neither microvascular proliferation nor necrosis are identified. Only a rare mitotic figure is seen at up to 1 mitoses per 10 high power fields. The histologic features are consistent with an infiltrating oligoastrocytoma.

Source: NCI Genomic Data Commons file abe84796-9631-462c-9421-1cb37aa69715 (TCGA-HT-7474.CEF17048-E651-4025-B26E-8D1FC30D0AF9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).